CCDI case PBCKWK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/cef910ae-e98c-477a-acc7-9d659b11fa52

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Tumor cells, uncertain whether benign or malignant: ICD-O-3 morphology code: 8001/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.7 years (3,898 days).

Biospecimens (3 samples)
- Sample 0DU9MQ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DU9N0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DU9NH: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
